Somatic mutation profile of tumor specimen TCGA-N7-A4Y0-01A (aliquot TCGA-N7-A4Y0-01A-12D-A28R-08) from TCGA case TCGA-N7-A4Y0, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Age at diagnosis: 65.7 years (23,983 days).
Specimen TCGA-N7-A4Y0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b661df48-fa74-41a6-b742-659b2b03afaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N7-A4Y0-10A (Blood Derived Normal), aliquot TCGA-N7-A4Y0-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7e1dfe3-8a9b-4c05-93a4-cc839317291d

The open-access MAF lists 899 somatic variants for this specimen: 701 protein-altering or splice-affecting, 184 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 436, Silent 184, Frame Shift Del 166, Frame Shift Ins 37, Nonsense Mutation 23, Splice Site 16, Splice Region 13, In Frame Del 9, Intron 7, RNA 4, 3'UTR 1, 5'UTR 1.

Variants (750 of 899; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33dup p.K12Qfs*156 | Frame Shift Ins (INS) | VAF 14/28 reads (50%) | catalogued as rs180177201; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ARSA | c.302dup p.L102Pfs*32 | Frame Shift Ins (INS) | VAF 7/16 reads (44%) | catalogued as rs761606317; ClinVar: pathogenic; called by mutect2, varscan2
- BIVM-ERCC5 | c.4113del p.K1371Nfs*65 | Frame Shift Del (DEL) | VAF 31/60 reads (52%) | catalogued as rs752661599, COSV100863757; ClinVar: pathogenic; called by mutect2, varscan2
- CCND1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57119102, COSV57119569, COSV57120578; called by muse, mutect2, varscan2
- CHD7 | c.8962dup p.D2988Gfs*2 | Frame Shift Ins (INS) | VAF 14/26 reads (54%) | catalogued as rs771806027, CI084262; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KMT2D | c.7479dup p.F2494Vfs*12 | Frame Shift Ins (INS) | VAF 24/85 reads (28%) | catalogued as rs1555192051; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.4379del p.P1460Hfs*46 | Frame Shift Del (DEL) | VAF 47/170 reads (28%) | catalogued as rs1240601136; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MC2R | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs104894661, CM960958, COSV59620540; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 94/153 reads (61%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- MYC | c.131C>T p.A44V (on ENST00000377970; = p.A59V on NM_002467.6) | Missense Mutation (SNP) | VAF 96/137 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775522201, COSV52367462, COSV99422212; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- NSD1 | c.5332C>T p.R1778* | Nonsense Mutation (SNP) | VAF 51/86 reads (59%) | catalogued as rs794727176, CM030076, COSV61785134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 138/228 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64288639; called by muse, mutect2, varscan2
- SHANK3 | c.3658dup p.A1220Gfs*69 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | catalogued as rs762292772; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA13 | c.1265T>C p.L422S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs1230448956; called by muse, mutect2
- ABCB6 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759447077, COSV54696551; called by muse, mutect2, varscan2
- ABCG8 | c.2017T>C p.W673R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs775121250; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 44/102 reads (43%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 33/87 reads (38%) | catalogued as COSV65879385; called by mutect2, pindel, varscan2
- ADCY6 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763081536; called by muse, varscan2
- ADGRA2 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 91/432 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as rs370919357; called by muse, mutect2, varscan2
- ADGRG4 | c.8874del p.F2958Lfs*6 | Frame Shift Del (DEL) | VAF 82/224 reads (37%) | catalogued as rs771931957; called by mutect2, varscan2
- ADRA2A | c.107del p.G36Afs*12 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | catalogued as rs1554870245; called by mutect2, varscan2
- AGXT | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.219); catalogued as CM034083; called by muse, mutect2, varscan2
- AHDC1 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.356); catalogued as rs766911404; called by muse, varscan2
- AHNAK | c.4294G>A p.A1432T | Missense Mutation (SNP) | VAF 122/314 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs139799392; called by muse, mutect2, varscan2
- AK8 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 109/266 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.369); catalogued as rs750120409, COSV53754113; called by muse, mutect2, varscan2
- AKR1C8P | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs555305935; called by muse, mutect2, varscan2
- ALK | c.3007A>G p.K1003E | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs775351719; called by muse, mutect2, varscan2
- AMER3 | c.585del p.R196Gfs*70 | Frame Shift Del (DEL) | VAF 36/80 reads (45%) | catalogued as COSV58470642; called by mutect2, varscan2
- ANK3 | c.9349del p.I3117Sfs*2 | Frame Shift Del (DEL) | VAF 73/230 reads (32%) | catalogued as rs370637835; called by mutect2, varscan2
- ANLN | c.2289_2291del p.L764del | In Frame Del (DEL) | VAF 32/77 reads (42%) | catalogued as rs770833202; called by pindel, varscan2
- APLP1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs761017755, COSV55703195, COSV55707221; called by muse, mutect2, varscan2
- APOA5 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs756286096, COSV99911554; called by muse, mutect2, varscan2
- ARHGAP10 | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs747924413; called by muse, mutect2, varscan2
- ARHGAP21 | c.4380del p.E1461Kfs*33 | Frame Shift Del (DEL) | VAF 67/204 reads (33%) | catalogued as rs1564945644; called by mutect2, pindel, varscan2
- ARHGAP29 | c.1835C>G p.T612R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1271335316, COSV99557673; called by muse, mutect2, varscan2
- ARHGAP39 | c.1095del p.S366Rfs*18 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs751388541; called by mutect2, pindel, varscan2
- ARID1A | c.1650dup p.Y551Lfs*72 | Frame Shift Ins (INS) | VAF 154/433 reads (36%) | catalogued as rs1415146710; called by mutect2, pindel, varscan2
- ARMCX2 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs1556059282, COSV100168078; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 28/66 reads (42%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASIC2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs565904010, COSV63314653; called by muse, mutect2, varscan2
- ASPHD1 | c.279G>A p.W93* | Nonsense Mutation (SNP) | VAF 63/156 reads (40%) | catalogued as COSV100435368; called by muse, mutect2, varscan2
- ASPRV1 | c.537del p.S180Afs*28 | Frame Shift Del (DEL) | VAF 41/99 reads (41%) | catalogued as rs751747496; called by mutect2, pindel, varscan2
- ATP6V0D2 | c.892-2A>G p.X298_splice | Splice Site (SNP) | VAF 120/196 reads (61%) | catalogued as rs998567000, COSV53415717; called by muse, mutect2, varscan2
- ATP9A | c.1571T>C p.M524T | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs1256434959; called by muse, mutect2, varscan2
- B4GAT1 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV100240214; called by muse, mutect2, varscan2
- BCL3 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV51234333; called by muse, mutect2
- BIRC6 | c.12497G>A p.R4166H | Missense Mutation (SNP) | VAF 96/235 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748782106; called by muse, mutect2, varscan2
- BMP1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1177387113, COSV60477449; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as COSV56263190; called by mutect2, pindel, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C11orf65 | c.67T>C p.W23R | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs982297600; called by muse, mutect2, varscan2
- C15orf39 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs548759069; called by muse, mutect2, varscan2
- C2orf42 | c.1230dup p.R411Tfs*29 | Frame Shift Ins (INS) | VAF 26/72 reads (36%) | catalogued as rs1214126095; called by mutect2, varscan2
- CACNB2 | c.355G>A p.V119I (on ENST00000324631 / NM_201596.3; = p.V64I on NM_000724.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.405); catalogued as COSV56631506; called by muse, mutect2, varscan2
- CALCR | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as rs1428691041; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 19/37 reads (51%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN9 | c.875+1G>A p.X292_splice | Splice Site (SNP) | VAF 42/109 reads (39%) | catalogued as COSV99680213; called by muse, mutect2, varscan2
- CCDC144A | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as COSV61403849; called by muse, mutect2, varscan2
- CCDC157 | c.1808A>G p.Q603R | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748490536; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC80 | c.1658del p.K553Rfs*2 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1253078189; called by mutect2, varscan2
- CD36 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs752841786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD37 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.276); catalogued as rs147415665; called by muse, mutect2, varscan2
- CDC42BPB | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs147856179, COSV63476421; called by muse, mutect2, varscan2
- CDH7 | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59889747; called by muse, mutect2
- CDH7 | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs763773954, COSV59895892; called by muse, mutect2, varscan2
- CELSR3 | c.6656C>T p.T2219I | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV50848743; called by muse, mutect2, varscan2
- CEP57 | c.661_663del p.E221del | In Frame Del (DEL) | VAF 19/55 reads (35%) | catalogued as rs746863051; called by pindel, varscan2
- CFAP221 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | catalogued as rs867214691, COSV54657856, COSV99733228; called by muse, mutect2, varscan2
- CHD4 | c.2183G>A p.W728* (on ENST00000357008 / NM_001363606.2; = p.W741* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 46/104 reads (44%) | catalogued as COSV58908358; called by muse, mutect2, varscan2
- CHODL | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.522); catalogued as COSV54734952; called by muse, mutect2, varscan2
- CHPF2 | c.1972dup p.A658Gfs*8 | Frame Shift Ins (INS) | VAF 16/35 reads (46%) | catalogued as rs756745837; called by mutect2, pindel, varscan2
- CIT | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs553305582, COSV55866226; called by muse, mutect2, varscan2
- CLDN5 | c.304G>A p.A102T (on ENST00000618236 / NM_001363066.2; = p.A187T on NM_003277.4) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1451497513; called by muse, mutect2, varscan2
- CLGN | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57776126; called by muse, mutect2, varscan2
- CLSTN3 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs755463631; called by muse, mutect2, varscan2
- CNPPD1 | c.1109C>G p.T370S | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778519106; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | catalogued as rs758676375; called by mutect2, varscan2
- COBL | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54354174; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | catalogued as rs748995811; called by mutect2, varscan2
- COL5A1 | c.2792G>C p.G931A | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65667890; called by muse, mutect2, varscan2
- COL5A3 | c.4317T>C p.G1439= | Splice Region (SNP) | VAF 39/97 reads (40%) | catalogued as COSV53409612; called by muse, mutect2, varscan2
- CPAMD8 | c.3153dup p.H1052Afs*30 (on ENST00000651564; = p.H1005Afs*30 on NM_015692.5) | Frame Shift Ins (INS) | VAF 20/44 reads (45%) | catalogued as rs750161916; called by mutect2, varscan2
- CRACDL | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs764688697, COSV67409553; called by muse, mutect2, varscan2
- CROCC | c.4609C>T p.R1537C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs764279779; called by muse, mutect2, varscan2
- CTCF | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 114/249 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV50504119; called by muse, mutect2, varscan2
- DDN | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as rs1168471331; called by muse, mutect2, varscan2
- DENND2B | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1483393269; called by muse, mutect2, varscan2
- DGKB | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1413885392, COSV51785383; called by muse, mutect2, varscan2
- DHX57 | c.1220T>A p.V407D | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV54882274; called by muse, mutect2, varscan2
- DNAH3 | c.10405G>T p.G3469* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV54546198, COSV99765477; called by muse, mutect2, varscan2
- DNAH7 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs371246623; called by muse, mutect2, varscan2
- DNASE2B | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs145614783; called by muse, mutect2, varscan2
- DNER | c.2189C>T p.T730I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs370899509; called by muse, mutect2, varscan2
- DTX4 | c.1188del p.K396Nfs*34 | Frame Shift Del (DEL) | VAF 5/9 reads (56%) | catalogued as rs1381179969; called by mutect2, varscan2
- DVL3 | c.1969G>A p.G657R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs551717443, COSV99490361; called by muse, mutect2, varscan2
- E2F1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58534588; called by muse, mutect2, varscan2
- E2F8 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 87/201 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755274793, COSV100001230; called by muse, mutect2, varscan2
- EBF2 | c.1448G>A p.S483N | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as rs756203261; called by muse, mutect2, varscan2
- ECE2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1168681969, COSV100668585; called by muse, mutect2
- EHBP1L1 | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as rs768779069; called by muse, mutect2, varscan2
- EHF | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs760166294; called by muse, mutect2, varscan2
- EI24 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs371870792; called by muse, mutect2, varscan2
- EIF4G2 | c.740T>C p.M247T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.072); catalogued as rs771110613, COSV60598998, COSV60599427; called by muse, mutect2, varscan2
- ENPP1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1396166711, COSV62931745; called by muse, mutect2, varscan2
- EPHA2 | c.2670C>T p.R890= | Splice Region (SNP) | VAF 13/45 reads (29%) | catalogued as rs1365728907; called by muse, mutect2, varscan2
- EPS15L1 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs767663912, COSV50168666; called by muse, mutect2, varscan2
- ERN2 | c.1399del p.L467Wfs*48 | Frame Shift Del (DEL) | VAF 37/106 reads (35%) | catalogued as rs763540496, COSV99078581; called by mutect2, pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 44/172 reads (26%) | catalogued as rs775950025; called by mutect2, varscan2
- EXD3 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs1205922453, COSV59804543; called by muse, mutect2, varscan2
- FAM214A | c.164T>A p.V55E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV55927346; called by muse, mutect2, varscan2
- FAM53B | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 72/123 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV61559970; called by muse, mutect2, varscan2
- FASN | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60763013; called by muse, mutect2, varscan2
- FBXW5 | c.1095C>T p.I365= | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as rs557711640; called by muse, mutect2, varscan2
- FER | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as rs1295416752; called by muse, mutect2, varscan2
- FER1L6 | c.2966T>C p.L989P | Missense Mutation (SNP) | VAF 128/186 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1346569810; called by muse, mutect2, varscan2
- FGF12 | c.367G>A p.A123T (on ENST00000454309 / NM_021032.5; = p.A61T on NM_004113.6) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs775684859, COSV53164750; called by muse, mutect2, varscan2
- FGFR2 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs371714070; called by muse, mutect2, varscan2
- FLG | c.5836G>A p.A1946T | Missense Mutation (SNP) | VAF 185/549 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs758157072, COSV100911159; called by muse, mutect2, varscan2
- FLRT1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761256926, COSV99734482; called by muse, mutect2, varscan2
- FMN2 | c.4925C>T p.T1642M | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.293); catalogued as rs774680818, COSV60433128; called by muse, mutect2, varscan2
- FOXG1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57395156; called by muse, mutect2, varscan2
- FRAS1 | c.1887dup p.K630Qfs*19 | Frame Shift Ins (INS) | VAF 40/90 reads (44%) | catalogued as rs776570778; called by mutect2, varscan2
- GABRE | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as rs774731784, COSV64819046; called by muse, mutect2, varscan2
- GIGYF1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1199797956, COSV99308822; called by muse, mutect2, varscan2
- GNAQ | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV54109441, COSV54115536; called by muse, varscan2
- GNL1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 109/192 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770630082, COSV100925397; called by muse, mutect2, varscan2
- GP1BA | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs749788312; called by muse, mutect2, varscan2
- GP2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1240280054; called by muse, mutect2, varscan2
- GPR1 | c.380del p.F127Sfs*2 | Frame Shift Del (DEL) | VAF 47/122 reads (39%) | catalogued as rs759796967; called by mutect2, pindel, varscan2
- GRAMD1A | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs747475800, COSV58766044; called by muse, mutect2, varscan2
- GSE1 | c.335del p.P112Lfs*13 | Frame Shift Del (DEL) | VAF 62/170 reads (36%) | catalogued as rs949717861; called by mutect2, pindel, varscan2
- GTF3C1 | c.5541del p.E1848Rfs*33 | Frame Shift Del (DEL) | VAF 41/118 reads (35%) | catalogued as rs763161381; called by mutect2, pindel, varscan2
- H3C3 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 84/136 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63550795; called by muse, mutect2, varscan2
- HBS1L | c.2003G>C p.R668P | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63200128; called by muse, mutect2
- HCLS1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 112/267 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs149387044; called by muse, mutect2, varscan2
- HDAC8 | c.325T>A p.F109I | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV104423985; called by muse, mutect2, varscan2
- HELLS | c.1840del p.R614Efs*11 | Frame Shift Del (DEL) | VAF 30/58 reads (52%) | catalogued as rs745837238; called by mutect2, varscan2
- HJURP | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs769465466, COSV64978867; called by muse, mutect2, varscan2
- HLA-DPA1 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs758878095; called by muse, mutect2, varscan2
- HPS5 | c.3365G>A p.R1122Q (on ENST00000349215 / NM_181507.2; = p.R1008Q on NM_007216.4) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as rs201017833, COSV100752347; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | catalogued as rs747841314; called by mutect2, varscan2
- IFIT1 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1472991339; called by muse, mutect2, varscan2
- IFNW1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs752514780, COSV66521875; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 84/272 reads (31%) | catalogued as rs760021495; called by mutect2, varscan2
- IL17REL | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs755837483, COSV58008198; called by muse, mutect2, varscan2
- ILDR2 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99614232; called by muse, mutect2
- INO80B | c.1035dup p.P346Afs*? | Frame Shift Ins (INS) | VAF 32/75 reads (43%) | catalogued as rs752165206; called by mutect2, varscan2
- INPP5D | c.1196C>T p.P399L (on ENST00000445964 / NM_001017915.3; = p.P398L on NM_005541.5) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs777189163, COSV64036195; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs760925109; called by pindel, varscan2
- INPPL1 | c.3470del p.G1157Dfs*45 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs1565399032, COSV53356328, COSV99996061; called by pindel, varscan2
- JAK3 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs749334592, COSV101512968; called by muse, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNQ4 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61274004; called by muse, mutect2, varscan2
- KIF21A | c.1629dup p.D544Rfs*20 (on ENST00000361418 / NM_001378440.1; = p.D544Rfs*19 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 30/70 reads (43%) | catalogued as rs1381571381; called by mutect2, varscan2
- KIF26A | c.3440del p.P1147Lfs*101 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs771825279; called by mutect2, pindel, varscan2
- KLC4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs756928667, COSV52434917; called by muse, mutect2, varscan2
- KLF16 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs891655829; called by muse, mutect2, varscan2
- KLHL25 | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs769248280; called by muse, mutect2, varscan2
- KRT4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767527715, COSV53406177; called by muse, mutect2, varscan2
- KTI12 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs755556446; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LGALS9 | c.1066T>C p.*356Qext*183 (on ENST00000395473 / NM_009587.3; = p.*324Qext*183 on NM_002308.4) | Nonstop Mutation (SNP) | VAF 76/217 reads (35%) | catalogued as rs201620769; called by muse, mutect2, varscan2
- LIN9 | c.1082G>T p.R361L (on ENST00000366808 / NM_001270410.2; = p.R306L on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100067458; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 23/69 reads (33%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP6 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs148238873; called by muse, mutect2, varscan2
- MAD1L1 | c.1708C>T p.R570* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs376905987; called by muse, varscan2
- MAPK15 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs371795375; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs375735836; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs771313856; called by muse, mutect2, varscan2
- MAPRE2 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs553548164, COSV100290671; called by muse, mutect2, varscan2
- MARCKS | c.980dup p.A328Sfs*14 | Frame Shift Ins (INS) | VAF 82/134 reads (61%) | catalogued as rs770972906; called by mutect2, varscan2
- MCF2L | c.1397C>T p.T466M (on ENST00000375608; = p.T434M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs751741111, COSV65047726; called by muse, mutect2, varscan2
- MCM2 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 90/201 reads (45%) | catalogued as rs1457321529; called by muse, mutect2, varscan2
- MCM3AP | c.5337del p.F1779Lfs*5 | Frame Shift Del (DEL) | VAF 44/123 reads (36%) | catalogued as COSV52437287; called by mutect2, pindel, varscan2
- MEIOB | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as rs755593711, COSV58053459; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 61/132 reads (46%) | catalogued as rs780635289; called by mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MINK1 | c.2941C>T p.R981W | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1364162614, COSV53418887; called by muse, mutect2, varscan2
- MORC4 | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs772865513, COSV55243507, COSV55246432; called by muse, mutect2, varscan2
- MSH4 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs1487084517, COSV99592208; called by muse, mutect2, varscan2
- MST1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755308635, COSV56536821; called by muse, mutect2, varscan2
- MYCT1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs375330501; called by muse, mutect2, varscan2
- MYD88 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322873412; called by muse, mutect2, varscan2
- MYF6 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 62/117 reads (53%) | catalogued as rs779208935, COSV57353191; called by muse, mutect2, varscan2
- MYLK | c.5002G>A p.E1668K | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750437332, COSV60606159; called by muse, mutect2, varscan2
- NCKAP5 | c.2593A>G p.I865V | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.061); catalogued as rs1335081108; called by muse, mutect2, varscan2
- NCOA1 | c.391G>T p.G131W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56041200; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 111/319 reads (35%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFAT5 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.009); catalogued as rs369476982; called by muse, mutect2, varscan2
- NFX1 | c.510del p.A171Qfs*154 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | catalogued as rs1564097639, COSV59314472; called by mutect2, pindel, varscan2
- NKPD1 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as rs759222968; called by muse, varscan2
- NOTCH3 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs1568357671, COSV54627056, COSV99656317; called by muse, mutect2, varscan2
- NRAP | c.676-2A>G p.X226_splice | Splice Site (SNP) | VAF 20/64 reads (31%) | catalogued as rs1385130629; called by muse, mutect2, varscan2
- NTN3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 96/230 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775996713, COSV99564964; called by muse, mutect2, varscan2
- NUB1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs761551992; called by muse, mutect2, varscan2
- NUDT14 | c.126C>T p.S42= | Splice Region (SNP) | VAF 17/39 reads (44%) | catalogued as rs370941955; called by muse, mutect2, varscan2
- NUDT5 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1475450706; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 66/412 reads (16%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP210 | c.2295G>A p.M765I | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs756021923; called by muse, mutect2, varscan2
- NYNRIN | c.3071C>T p.A1024V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1219040529; called by muse, mutect2, varscan2
- OAF | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs771067831; called by muse, mutect2, varscan2
- OGFOD3 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1303122247, COSV57340723; called by muse, mutect2, varscan2
- OPCML | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs767079791, COSV59455705; called by muse, mutect2, varscan2
- OPRD1 | c.579C>T p.D193= | Splice Region (SNP) | VAF 24/48 reads (50%) | catalogued as rs1177560846; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 88/170 reads (52%) | catalogued as rs753966040; called by mutect2, varscan2
- OR1A1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs371610534; called by muse, mutect2
- OR2L2 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs914168723, COSV63552073; called by muse, mutect2, varscan2
- OR2W3 | c.850del p.L284Sfs*14 | Frame Shift Del (DEL) | VAF 34/64 reads (53%) | catalogued as rs1268396241; called by mutect2, varscan2
- OR4C6 | c.180del p.T62Pfs*18 | Frame Shift Del (DEL) | VAF 54/156 reads (35%) | catalogued as rs781182602; called by mutect2, pindel, varscan2
- OR51A7 | c.380A>G p.H127R | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs551503798; called by muse, mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 42/110 reads (38%) | catalogued as rs1564877761; called by mutect2, varscan2
- OR7C2 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 82/200 reads (41%) | catalogued as rs747041500; called by mutect2, pindel, varscan2
- P2RY12 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs1476732178; called by muse, mutect2, varscan2
- PASD1 | c.1718A>C p.K573T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV64854196; called by muse, mutect2, varscan2
- PCDH10 | c.1906G>A p.G636R | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429679034, COSV52088867; called by muse, mutect2, varscan2
- PCDHA6 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 115/264 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781852790, COSV100972045; called by muse, mutect2, varscan2
- PCDHB15 | c.2218A>G p.S740G | Missense Mutation (SNP) | VAF 223/376 reads (59%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.354); catalogued as COSV99178828; called by muse, mutect2, varscan2
- PCDHB6 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 116/252 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV50701615; called by muse, varscan2
- PCDHGB7 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53907917; called by muse, mutect2, varscan2
- PCNX3 | c.5062C>T p.R1688C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1198280803, COSV63136638; called by muse, mutect2, varscan2
- PIK3C3 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.662); catalogued as COSV100011565; called by muse, mutect2, varscan2
- PIK3CG | c.505C>T p.H169Y | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV104418601; called by muse, mutect2, varscan2
- PITPNM1 | c.2969C>T p.A990V | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs764838275; called by muse, varscan2
- PJVK | c.823del p.S275Lfs*10 | Frame Shift Del (DEL) | VAF 18/161 reads (11%) | catalogued as rs757539839, COSV51846961; called by mutect2, pindel, varscan2
- PKD1 | c.4804C>T p.R1602C | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748423575, CD163932; called by muse, mutect2, varscan2
- PKD1 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs951742398; called by mutect2, varscan2
- PLA2R1 | c.4119del p.G1374Afs*32 | Frame Shift Del (DEL) | VAF 68/148 reads (46%) | catalogued as rs746999253; called by mutect2, varscan2
- PLCH1 | c.2503+2T>C p.X835_splice (on ENST00000340059 / NM_001130960.2; = p.X847_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 28/60 reads (47%) | catalogued as rs1553797103; called by muse, mutect2, varscan2
- PLCXD1 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs764474227, COSV58204437; called by muse, mutect2, varscan2
- PLEC | c.6547C>T p.R2183W (on ENST00000322810 / NM_201380.4; = p.R2073W on NM_000445.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.727); catalogued as rs782634097; called by muse, mutect2
- PLEKHA5 | c.929dup p.N310Kfs*8 | Frame Shift Ins (INS) | VAF 22/47 reads (47%) | catalogued as rs1565550899; called by mutect2, varscan2
- PLEKHG4B | c.976C>T p.Q326* (on ENST00000283426; = p.Q682* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 36/76 reads (47%) | catalogued as rs373010753; called by muse, mutect2, varscan2
- PNMA2 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs999026700; called by muse, mutect2, varscan2
- PNPLA6 | c.3605G>A p.R1202H (on ENST00000414982 / NM_001166111.2; = p.R1154H on NM_006702.5) | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1395876279, COSV99653086; called by muse, mutect2, varscan2
- PODN | c.908C>G p.P303R (on ENST00000395871; = p.P255R on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs200853703, COSV100439932, COSV57012343; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLG | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs74382477, COSV51519376; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- POMT1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.437); catalogued as rs530211718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 36/102 reads (35%) | catalogued as rs778683789; called by mutect2, varscan2
- PREX2 | c.2459G>A p.G820D | Missense Mutation (SNP) | VAF 128/177 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758520881, COSV55763290; called by muse, mutect2, varscan2
- PRKDC | c.4349C>T p.A1450V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.055); catalogued as rs567674136; called by muse, varscan2
- PRRC2A | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs772781740; called by muse, mutect2, varscan2
- PSD2 | c.2140C>A p.L714I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV99217437; called by muse, mutect2, varscan2
- PTEN | c.700dup p.R234Pfs*9 | Frame Shift Ins (INS) | VAF 36/147 reads (24%) | catalogued as COSV64297284, COSV64298744, COSV64298782, COSV99057998, COSV99058007; called by mutect2, pindel, varscan2
- PTGFRN | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190695040, COSV67798274; called by muse, mutect2, varscan2
- PXDNL | c.1794G>T p.T598= | Splice Region (SNP) | VAF 20/69 reads (29%) | catalogued as COSV62487597, COSV62491744; called by muse, mutect2, varscan2
- RAC3 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs760585885, COSV60711965; called by muse, mutect2
- RASSF7 | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV100272723; called by muse, mutect2
- RB1CC1 | c.907T>C p.F303L | Missense Mutation (SNP) | VAF 122/174 reads (70%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs772801563; called by muse, mutect2, varscan2
- RBM25 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1004149613; called by muse, mutect2, varscan2
- RERE | c.4477C>T p.P1493S | Missense Mutation (SNP) | VAF 130/321 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61948025; called by muse, mutect2, varscan2
- RGS7 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs149172715; called by muse, mutect2, varscan2
- RIMBP2 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs370841973; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF169 | c.1827C>G p.S609R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs773751655; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 86/212 reads (41%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROGDI | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs750166706, COSV59020696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ROR2 | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.484); catalogued as rs146067291; called by muse, mutect2, varscan2
- RPA4 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61260783; called by muse, mutect2, varscan2
- RREB1 | c.4338del p.E1447Rfs*81 | Frame Shift Del (DEL) | VAF 9/10 reads (90%) | catalogued as COSV58560368; called by mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs747510098; called by mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 53/116 reads (46%) | catalogued as rs756606313; called by mutect2, varscan2
- RUSC2 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs771012780, COSV63428578; called by muse, mutect2, varscan2
- RXFP3 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57504811; called by muse, mutect2, varscan2
- S1PR2 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.923); catalogued as rs1341722748; called by muse, mutect2, varscan2
- SARDH | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as rs751568063; called by muse, mutect2, varscan2
- SHANK1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); catalogued as rs138468869; called by muse, mutect2, varscan2
- SLC12A4 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs951418368, COSV57927872; called by muse, mutect2, varscan2
- SLC16A11 | c.125C>T p.A42V (on ENST00000308009; = p.A18V on NM_153357.3) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1489548656, COSV57274783; called by muse, mutect2, varscan2
- SLC20A2 | c.1882G>A p.V628M | Missense Mutation (SNP) | VAF 87/157 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs200761348; called by muse, mutect2, varscan2
- SLC25A25 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1231750255; called by muse, mutect2, varscan2
- SLC34A2 | c.1229C>A p.P410H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65941407; called by muse, mutect2, varscan2
- SLC66A2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 125/281 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs750494826; called by muse, mutect2, varscan2
- SMAD7 | c.626dup p.P210Sfs*25 | Frame Shift Ins (INS) | VAF 18/55 reads (33%) | catalogued as rs747624971; called by mutect2, varscan2
- SORBS2 | c.674A>G p.H225R (on ENST00000284776 / NM_021069.5; = p.H271R on NM_003603.6) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as rs1435921816; called by muse, mutect2, varscan2
- SORCS3 | c.2644del p.V882Cfs*10 | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | catalogued as COSV63797293; called by mutect2, pindel, varscan2
- SPATA31D1 | c.2310dup p.N771Efs*30 | Frame Shift Ins (INS) | VAF 31/93 reads (33%) | catalogued as rs34942699; called by mutect2, pindel, varscan2
- SPSB1 | c.370del p.L124Cfs*56 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | catalogued as COSV60165026; called by mutect2, pindel, varscan2
- SPTBN4 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs749087626, COSV58945861; called by muse, mutect2, varscan2
- SQLE | c.254del p.P85Lfs*25 | Frame Shift Del (DEL) | VAF 30/68 reads (44%) | catalogued as rs760774524; called by mutect2, pindel, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 70/183 reads (38%) | catalogued as rs748467821; called by mutect2, varscan2
- SRRM4 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as rs755901947; called by muse, mutect2
- TBC1D16 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs766476353; called by muse, mutect2, varscan2
- TEAD2 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 42/99 reads (42%) | catalogued as rs1170474435; called by muse, mutect2, varscan2
- TGFBI | c.1565T>C p.I522T | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM098879; called by muse, mutect2, varscan2
- THAP7 | c.343del p.A115Lfs*156 | Frame Shift Del (DEL) | VAF 75/200 reads (38%) | catalogued as COSV53145439; called by mutect2, pindel, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TIMM10B | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0.048); catalogued as COSV54447556; called by muse, mutect2, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 56/179 reads (31%) | catalogued as rs760930120; called by mutect2, varscan2
- TMEM102 | c.624A>C p.K208N | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV53440911; called by muse, mutect2, varscan2
- TMEM106A | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 134/327 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751877962, COSV59045809; called by muse, mutect2, varscan2
- TMEM176B | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 29/95 reads (31%) | catalogued as COSV58439766; called by muse, mutect2, varscan2
- TNXB | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766329025; called by muse, mutect2, varscan2
- TSPAN31 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs751196445; called by muse, mutect2, varscan2
- TSTD2 | c.1214A>G p.E405G | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs544945853; called by muse, mutect2, varscan2
- TTC22 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs762407457, COSV64881765; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 53/59 reads (90%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.27043G>A p.V9015M (on ENST00000591111; = p.V8088M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/208 reads (32%) | PolyPhen probably damaging (0.983); catalogued as rs367734747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3D | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs756548886; called by muse, varscan2
- TUBA8 | c.417_418del p.H139Qfs*72 | Frame Shift Del (DEL) | VAF 48/189 reads (25%) | catalogued as rs572043266; called by pindel, varscan2
- UBE2G1 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 111/302 reads (37%) | catalogued as COSV67833573; called by muse, mutect2, varscan2
- UGCG | c.1094dup p.L365Ffs*36 | Frame Shift Ins (INS) | VAF 17/115 reads (15%) | catalogued as rs1243652090; called by mutect2, varscan2
- UGT2B28 | c.1307C>A p.P436H | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59434256; called by muse, mutect2, varscan2
- USP20 | c.1100C>A p.P367Q | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.055); catalogued as rs746240662; called by muse, mutect2, varscan2
- UTP20 | c.7133G>A p.R2378H | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs573079112; called by muse, mutect2, varscan2
- VIPAS39 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.874); catalogued as rs761604651, COSV53632494; called by muse, mutect2, varscan2
- VPS35L | c.2721_2723del p.N907del | In Frame Del (DEL) | VAF 34/99 reads (34%) | catalogued as rs760572158; called by pindel, varscan2
- VPS52 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1206051206, COSV101460430; called by muse, mutect2, varscan2
- VSIR | c.856del p.L286Cfs*51 | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | catalogued as rs752718137, COSV56484595; called by mutect2, pindel, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs746919573; called by mutect2, varscan2
- WFS1 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs749886570, CD993078, COSV56991808; called by muse, mutect2, varscan2
- WNT5B | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1320799013, COSV60197680; called by muse, mutect2
- WWC1 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 137/249 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); catalogued as rs375638687; called by muse, mutect2, varscan2
- XRRA1 | c.2101del p.R701Gfs*8 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as COSV55131646; called by mutect2, pindel, varscan2
- YEATS2 | c.3142G>A p.V1048I | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.146); catalogued as rs762802940, COSV59367708; called by muse, mutect2, varscan2
- ZC3H11A | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV59749700; called by muse, mutect2, varscan2
- ZC3H18 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs562706352; called by muse, mutect2, varscan2
- ZC3H6 | c.475T>C p.Y159H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV59669344; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFP36L2 | c.683del p.G228Afs*233 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as COSV99144234; called by mutect2, pindel, varscan2
- ZFPM2 | c.2745del p.K915Nfs*8 | Frame Shift Del (DEL) | VAF 36/69 reads (52%) | catalogued as COSV65873861; called by mutect2, pindel, varscan2
- ZIC4 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs1231020134, COSV67172263, COSV67172625; called by muse, mutect2, varscan2
- ZNF260 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1291721077; called by muse, mutect2, varscan2
- ZNF518B | c.572A>G p.Q191R | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1291300823; called by muse, mutect2, varscan2
- AARS1 | c.2394del p.G799Efs*24 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- AC090517.4 | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACR | c.493dup p.H165Pfs*3 | Frame Shift Ins (INS) | VAF 58/162 reads (36%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.2878C>T p.P960S | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ADCY3 | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ADGRA1 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADH4 | c.1132C>A p.L378I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.234); called by mutect2, varscan2
- AEBP1 | c.343A>G p.R115G | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFP | c.1102T>C p.S368P | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHI1 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ALDH1A1 | c.258del p.R87Dfs*9 | Frame Shift Del (DEL) | VAF 52/142 reads (37%) | called by mutect2, pindel, varscan2
- ANK3 | c.7727G>T p.R2576M | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKAR | c.3712G>C p.A1238P | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5011C>T p.P1671S | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANO4 | c.1219A>G p.M407V (on ENST00000392977 / NM_001286615.2; = p.M372V on NM_178826.4) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- AP1G2 | c.977+2T>C p.X326_splice | Splice Site (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- AP3M2 | c.613del p.V205* | Frame Shift Del (DEL) | VAF 19/100 reads (19%) | called by mutect2, pindel, varscan2
- ARHGAP11A | c.375del p.F125Lfs*18 | Frame Shift Del (DEL) | VAF 29/94 reads (31%) | called by mutect2, pindel, varscan2
- ARHGAP27 | c.2423G>T p.R808L (on ENST00000428638 / NM_001282290.1; = p.R467L on NM_199282.3) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ARHGAP32 | c.3149C>T p.S1050F (on ENST00000310343 / NM_001378025.1; = p.S701F on NM_014715.4) | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP35 | c.2814del p.F938Lfs*10 | Frame Shift Del (DEL) | VAF 68/194 reads (35%) | called by mutect2, pindel, varscan2
- ARHGEF26 | c.1450T>C p.F484L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 58/159 reads (36%) | called by mutect2, pindel, varscan2
- ARL14EP | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARL16 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARSD | c.1135+2T>C p.X379_splice | Splice Site (SNP) | VAF 26/306 reads (8%) | called by muse, mutect2
- ARSL | c.1311_1313del p.L438del | In Frame Del (DEL) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- ARX | c.905C>A p.A302D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ASTE1 | c.690del p.I231Sfs*6 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | called by mutect2, pindel, varscan2
- ASXL2 | c.775A>G p.R259G | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ATG13 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ATM | c.4850T>G p.L1617R | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATP11C | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 38/120 reads (32%) | called by muse, varscan2
- ATP8A2 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATRX | c.4885A>G p.N1629D | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATXN7L3 | c.713G>A p.R238Q (on ENST00000389384 / NM_001382309.1; = p.R245Q on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- B4GALNT2 | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- BCAS3 | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BCL2L1 | c.601G>A p.A201T (on ENST00000307677 / NM_001317919.2; = p.A138T on NM_001191.4) | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BEGAIN | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- BMP15 | c.1084T>C p.Y362H | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BOC | c.1944A>C p.K648N | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- BRWD1 | c.4369C>A p.L1457I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, varscan2
- C7 | c.1878T>A p.C626* | Nonsense Mutation (SNP) | VAF 67/182 reads (37%) | called by muse, mutect2, varscan2
- C8A | c.1341del p.R448Gfs*3 | Frame Shift Del (DEL) | VAF 32/78 reads (41%) | called by mutect2, pindel, varscan2
- CALML4 | c.555del p.F185Lfs*24 | Frame Shift Del (DEL) | VAF 36/79 reads (46%) | called by mutect2, pindel, varscan2
- CANT1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CANX | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD2BP2 | c.734del p.P245Hfs*37 | Frame Shift Del (DEL) | VAF 32/109 reads (29%) | called by mutect2, pindel, varscan2
- CDC42BPB | c.1026del p.F342Lfs*4 | Frame Shift Del (DEL) | VAF 43/126 reads (34%) | called by mutect2, pindel, varscan2
- CDH20 | c.2201A>G p.D734G | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CETN2 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CFAP43 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CFAP43 | c.949C>A p.L317M | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- CFAP58 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CHD6 | c.2988del p.S999Pfs*19 | Frame Shift Del (DEL) | VAF 102/432 reads (24%) | called by pindel, varscan2
- CNOT11 | c.1052A>G p.E351G | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- COL4A2 | c.1922C>A p.P641H | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- COL8A1 | c.1034del p.P345Qfs*36 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- COLGALT1 | c.1602G>A p.V534= | Splice Region (SNP) | VAF 197/513 reads (38%) | called by muse, mutect2, varscan2
- CPAMD8 | c.1141G>A p.D381N (on ENST00000651564; = p.D334N on NM_015692.5) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRNN | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CROT | c.328T>C p.F110L | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRTC2 | c.1242dup p.S415Lfs*62 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.5894A>C p.Q1965P | Missense Mutation (SNP) | VAF 90/153 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.2267A>G p.Q756R | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CXXC1 | c.640-1G>T p.X214_splice | Splice Site (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- CXorf21 | c.174C>A p.C58* | Nonsense Mutation (SNP) | VAF 105/249 reads (42%) | called by muse, mutect2, varscan2
- DAB1 | c.518del p.K173Rfs*68 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- DAB2 | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DBH | c.895C>A p.L299M | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DENND3 | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DGKH | c.1370G>A p.W457* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2
- DGKI | c.715G>T p.G239* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- DHX29 | c.2429A>G p.E810G | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- DHX37 | c.1684dup p.A562Gfs*19 | Frame Shift Ins (INS) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- DNAH10 | c.13259T>C p.V4420A (on ENST00000409039; = p.V4359A on NM_207437.3) | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DNAH17 | c.12390del p.N4131Tfs*34 | Frame Shift Del (DEL) | VAF 36/165 reads (22%) | called by mutect2, pindel, varscan2
- DNAH9 | c.8993A>C p.Q2998P | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- DNAJC16 | c.818_819del p.H273Rfs*5 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | called by mutect2, pindel, varscan2
- DOLK | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DOP1A | c.138+2T>C p.X46_splice | Splice Site (SNP) | VAF 125/211 reads (59%) | called by muse, mutect2, varscan2
- DSP | c.6301del p.S2101Qfs*15 | Frame Shift Del (DEL) | VAF 192/389 reads (49%) | called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.2723A>G p.H908R | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2160del p.A721Qfs*139 | Frame Shift Del (DEL) | VAF 66/162 reads (41%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.3121del p.A1041Pfs*13 | Frame Shift Del (DEL) | VAF 137/439 reads (31%) | called by pindel, varscan2
- ELAC2 | c.2106_2107del p.H702Qfs*46 | Frame Shift Del (DEL) | VAF 130/446 reads (29%) | called by pindel, varscan2
- ELL | c.811_813del p.K271del | In Frame Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- EPG5 | c.5704del p.Y1902Ifs*26 | Frame Shift Del (DEL) | VAF 46/115 reads (40%) | called by mutect2, pindel, varscan2
- EPPK1 | c.108del p.R37Gfs*7 | Frame Shift Del (DEL) | VAF 33/155 reads (21%) | called by mutect2, pindel, varscan2
- ERICH1 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 64/309 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ERRFI1 | c.490_491del p.L164Gfs*2 | Frame Shift Del (DEL) | VAF 39/116 reads (34%) | called by pindel, varscan2
- EZR | c.1412del p.P471Rfs*11 | Frame Shift Del (DEL) | VAF 85/171 reads (50%) | called by mutect2, pindel, varscan2
- FAAH2 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM135B | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM168B | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FAM193B | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FAM214B | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO41 | c.1971del p.N658Tfs*3 | Frame Shift Del (DEL) | VAF 11/110 reads (10%) | called by mutect2, pindel, varscan2
- FBXO45 | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FBXO8 | c.654del p.R219Vfs*17 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | called by mutect2, pindel, varscan2
- FHDC1 | c.11T>G p.M4R | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FLNA | c.3734G>T p.S1245I | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FLT3LG | c.464A>T p.E155V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FOCAD | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMPD4 | c.468+2T>C p.X156_splice | Splice Site (SNP) | VAF 5/136 reads (4%) | called by muse, mutect2
- FZD3 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- G6PD | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.03); called by muse, varscan2
- GAS2L2 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- GATA1 | c.1073del p.P358Qfs*74 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- GEM | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GFOD2 | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- GFPT1 | c.2050T>C p.Y684H (on ENST00000357308 / NM_001244710.2; = p.Y666H on NM_002056.4) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- GLP2R | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GMEB2 | c.227T>C p.L76S | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- GNB1L | c.735G>C p.V245= | Splice Region (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- GPR158 | c.1686del p.T564Hfs*18 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- GPR61 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRC5A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRB14 | c.1453del p.I485* | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | called by mutect2, pindel, varscan2
- GRIK2 | c.1867+2T>C p.X623_splice | Splice Site (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- GRK7 | c.635del p.N212Tfs*16 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- GRM5 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GSR | c.1259dup p.I421Yfs*10 | Frame Shift Ins (INS) | VAF 22/140 reads (16%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.5741del p.P1914Qfs*30 | Frame Shift Del (DEL) | VAF 75/243 reads (31%) | called by mutect2, pindel, varscan2
- HBP1 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- HCFC2 | c.926del p.N309Ifs*32 | Frame Shift Del (DEL) | VAF 44/94 reads (47%) | called by mutect2, varscan2
- HDAC7 | c.2304del p.M769Wfs*12 (on ENST00000427332; = p.M808Wfs*12 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | called by mutect2, pindel, varscan2
- HECTD2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- HECTD4 | c.10771G>A p.E3591K | Missense Mutation (SNP) | VAF 142/341 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HERC2 | c.11641T>C p.S3881P | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- HIF1A | c.1574G>T p.S525I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HIP1 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- HK2 | c.2168C>T p.T723I | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXB1 | c.428del p.P143Lfs*41 | Frame Shift Del (DEL) | VAF 27/85 reads (32%) | called by mutect2, pindel, varscan2
- HOXD1 | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); called by muse, mutect2
- ICE2 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- IFNW1 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- IFT122 | c.1981del p.T661Qfs*15 (on ENST00000348417 / NM_052989.3; = p.T602Qfs*15 on NM_018262.4) | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | called by mutect2, pindel, varscan2
- IGF2R | c.7399G>A p.A2467T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IGKV2-28 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by mutect2, varscan2
- IL4I1 | c.1527del p.P510Lfs*? | Frame Shift Del (DEL) | VAF 29/69 reads (42%) | called by mutect2, pindel, varscan2
- INTS12 | c.919_921del p.T307del | In Frame Del (DEL) | VAF 38/102 reads (37%) | called by mutect2, pindel, varscan2
- IPO7 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IRS1 | c.1564C>T p.R522* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- ISLR2 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ITGA9 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ITGAX | c.1949T>C p.V650A | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR3 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 95/192 reads (49%) | called by mutect2, pindel, varscan2
- JMJD4 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- KCNA3 | c.416A>G p.Y139C | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KDM4B | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KDM5C | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KIAA0895L | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIAA1217 | c.4195del p.E1399Rfs*24 | Frame Shift Del (DEL) | VAF 36/94 reads (38%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.5713G>A p.G1905S (on ENST00000422774 / NM_001164665.2; = p.G1889S on NM_020910.3) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- KIAA1549L | c.3067C>T p.Q1023* (on ENST00000321505; = p.Q1320* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 64/173 reads (37%) | called by muse, mutect2, varscan2
- KLHDC4 | c.339del p.S114Vfs*13 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | called by mutect2, pindel, varscan2
- KLHL31 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- KLKB1 | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- KMT2B | c.8091del p.S2698Afs*40 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | called by mutect2, pindel, varscan2
- KMT2C | c.8950del p.S2984Lfs*6 | Frame Shift Del (DEL) | VAF 26/57 reads (46%) | called by mutect2, pindel, varscan2
- KMT2C | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KMT2D | c.14480G>A p.G4827D | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KREMEN2 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT12 | c.164del p.G55Efs*56 | Frame Shift Del (DEL) | VAF 33/101 reads (33%) | called by mutect2, pindel, varscan2
- KRT222 | c.121del p.M41Wfs*8 | Frame Shift Del (DEL) | VAF 58/159 reads (36%) | called by mutect2, pindel, varscan2
- KRT76 | c.1798T>A p.S600T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- KRTAP13-4 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- L1CAM | c.3324C>T p.G1108= | Splice Region (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- L3MBTL2 | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LCT | c.3602C>T p.A1201V | Missense Mutation (SNP) | VAF 117/247 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGR4 | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- LMCD1 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 119/260 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- LRBA | c.5024del p.N1675Tfs*4 | Frame Shift Del (DEL) | VAF 28/97 reads (29%) | called by mutect2, pindel, varscan2
- LRP1B | c.1208dup p.N403Kfs*2 | Frame Shift Ins (INS) | VAF 31/109 reads (28%) | called by mutect2, pindel, varscan2
- LRP4 | c.1732del p.R578Vfs*233 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by mutect2, pindel, varscan2
- LTA | c.563T>C p.I188T | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2
- LZTFL1 | c.127A>G p.R43G | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MAGEE1 | c.1478A>C p.Q493P | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- MAGEL2 | c.2984A>G p.E995G | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K5 | c.1357C>G p.R453G | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 32/85 reads (38%) | called by mutect2, varscan2
- MATN4 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MC1R | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- MCM2 | c.574del p.R192Gfs*41 | Frame Shift Del (DEL) | VAF 36/125 reads (29%) | called by mutect2, pindel, varscan2
- MDM1 | c.56del p.K19Sfs*26 | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | called by mutect2, pindel, varscan2
- MED13 | c.3499A>G p.R1167G | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MMRN1 | c.485C>G p.T162S | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORC1 | c.670A>G p.M224V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MRTFB | c.3245G>A p.S1082N (on ENST00000571589 / NM_001365412.2; = p.S1032N on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MTFMT | c.712del p.A238Rfs*14 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by pindel, varscan2
- MTSS2 | c.1347G>T p.M449I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MYBL2 | c.1433T>C p.V478A | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- MYCBP2 | c.1124del p.K375Sfs*4 (on ENST00000357337; = p.K413Sfs*4 on NM_015057.5) | Frame Shift Del (DEL) | VAF 52/156 reads (33%) | called by mutect2, pindel, varscan2
- MYH10 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO6 | c.3869T>C p.L1290P (on ENST00000369981; = p.L1280P on NM_004999.4) | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOZ1 | c.598del p.M200Wfs*39 | Frame Shift Del (DEL) | VAF 43/187 reads (23%) | called by mutect2, pindel, varscan2
- NAA10 | c.393T>A p.S131R | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NAT16 | c.452A>G p.H151R | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NCKAP5 | c.1353del p.C452Afs*21 | Frame Shift Del (DEL) | VAF 22/43 reads (51%) | called by mutect2, pindel, varscan2
- NCOA2 | c.2725del p.S909Vfs*5 | Frame Shift Del (DEL) | VAF 36/139 reads (26%) | called by mutect2, pindel, varscan2
- NCOR2 | c.2925del p.I976Sfs*87 | Frame Shift Del (DEL) | VAF 121/348 reads (35%) | called by mutect2, pindel, varscan2
- NET1 | c.535A>G p.I179V (on ENST00000355029 / NM_001047160.3; = p.I125V on NM_005863.5) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NEXN | c.1769del p.N590Tfs*5 | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | called by mutect2, pindel, varscan2
- NKX2-1 | c.442del p.D148Tfs*2 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- NLRP2 | c.2202-1G>T p.X734_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- NOXO1 | c.337C>T p.R113C (on ENST00000397280 / NM_172168.3; = p.R107C on NM_144603.4) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NPTXR | c.1011del p.F338Sfs*15 | Frame Shift Del (DEL) | VAF 57/171 reads (33%) | called by mutect2, pindel, varscan2
- OR2A14 | c.610T>A p.F204I | Missense Mutation (SNP) | VAF 132/283 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- OR4K13 | c.543del p.V184* | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by pindel, varscan2
- OR4K13 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, varscan2
- OR6V1 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- ORC2 | c.1390_1391del p.L464Sfs*11 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | called by pindel, varscan2
- P2RX2 | c.314del p.X105_splice | Splice Site (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- PACSIN3 | c.1025del p.P342Rfs*27 | Frame Shift Del (DEL) | VAF 24/89 reads (27%) | called by mutect2, pindel, varscan2
- PAK4 | c.721dup p.Q241Pfs*62 | Frame Shift Ins (INS) | VAF 17/39 reads (44%) | called by mutect2, pindel, varscan2
- PCDH12 | c.2728C>A p.L910M | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCDHB14 | c.1237_1238del p.S413Pfs*30 | Frame Shift Del (DEL) | VAF 86/232 reads (37%) | called by pindel, varscan2
- PCDHGB1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE4D | c.784T>A p.S262T (on ENST00000340635 / NM_001104631.2; = p.S126T on NM_006203.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PDGFRB | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PDPR | c.2476del p.E826Kfs*5 | Frame Shift Del (DEL) | VAF 21/134 reads (16%) | called by mutect2, pindel, varscan2
- PELI3 | c.796T>C p.Y266H | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PHIP | c.1769dup p.L590Ffs*3 | Frame Shift Ins (INS) | VAF 35/130 reads (27%) | called by mutect2, pindel, varscan2
- PI4KB | c.2347_2349del p.E783del (on ENST00000368873 / NM_001369623.1; = p.E795del on NM_002651.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 31/83 reads (37%) | called by pindel, varscan2
- PIF1 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3C2G | c.1490A>G p.Y497C | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PIK3R1 | c.1352_1358delinsT p.E451_N453delinsV (on ENST00000521381 / NM_181523.3; = p.E181_N183delinsV on NM_181504.4) | In Frame Del (DEL) | VAF 21/67 reads (31%) | called by pindel, varscan2*
- PLEKHA8 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PLSCR3 | c.725del p.G242Afs*23 | Frame Shift Del (DEL) | VAF 65/192 reads (34%) | called by mutect2, pindel, varscan2
- POLH | c.54del p.F18Lfs*12 | Frame Shift Del (DEL) | VAF 123/284 reads (43%) | called by mutect2, pindel, varscan2
- POSTN | c.2196del p.K732Nfs*13 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- PRKD3 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRNP | c.640T>G p.C214G | Missense Mutation (SNP) | VAF 72/114 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPF40B | c.2351dup p.K785Efs*3 (on ENST00000380281; = p.K772Efs*3 on NM_012272.3) | Frame Shift Ins (INS) | VAF 20/41 reads (49%) | called by mutect2, varscan2
- PSD3 | c.1228_1229dup p.D410Efs*73 | Frame Shift Ins (INS) | VAF 67/122 reads (55%) | called by mutect2, varscan2
- PTCH1 | c.1633G>T p.G545* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- PTPRD | c.692-1G>A p.X231_splice | Splice Site (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- PTPRK | c.1352A>G p.Q451R | Missense Mutation (SNP) | VAF 93/144 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRM | c.2162C>T p.T721I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PTPRT | c.1714A>G p.K572E | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- PUS7L | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- QSOX2 | c.1286del p.P429Rfs*11 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- RAB11A | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- RABGGTA | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAD51AP2 | c.858del p.E287Rfs*31 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- RAI1 | c.2396del p.P799Lfs*20 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- RAMP2 | c.168del p.X56_splice | Splice Site (DEL) | VAF 92/204 reads (45%) | called by mutect2, varscan2
- RASAL3 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- RASGRP1 | c.1396del p.T466Pfs*43 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- RASIP1 | c.1254del p.S419Pfs*216 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | called by mutect2, varscan2
- RBCK1 | c.169C>G p.L57V (on ENST00000356286 / NM_031229.4; = p.L15V on NM_006462.6) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- RBM17 | c.46del p.T16Qfs*17 | Frame Shift Del (DEL) | VAF 47/178 reads (26%) | called by mutect2, pindel, varscan2
- RBM41 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RBMX | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- RFC5 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RIC1 | c.4206G>T p.E1402D | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMS2 | c.1309A>G p.R437G (on ENST00000666250 / NM_001348490.2; = p.R245G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, mutect2
- RNF150 | c.295C>A p.R99S | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); called by muse, mutect2
- RNF39 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF41 | c.892dup p.D298Gfs*2 | Frame Shift Ins (INS) | VAF 113/276 reads (41%) | called by mutect2, pindel, varscan2
- RNPEPL1 | c.1888T>C p.S630P | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ROCK2 | c.3923del p.K1308Rfs*5 | Frame Shift Del (DEL) | VAF 31/96 reads (32%) | called by mutect2, pindel, varscan2
- RPS6KL1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPUSD2 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- RTKN2 | c.542C>T p.T181I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- RTL9 | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 50/470 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2
- S100A13 | c.154-2A>G p.X52_splice | Splice Site (SNP) | VAF 112/234 reads (48%) | called by muse, mutect2, varscan2
- SAFB | c.2026G>A p.V676M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- SCAF4 | c.945_959+6delinsACAGGCACCATTGTTAG p.X315_splice | Splice Site (DEL) | VAF 18/46 reads (39%) | called by pindel, varscan2*
- SCARB2 | c.1113T>G p.P371= | Splice Region (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- SCN8A | c.4855A>G p.I1619V | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- SCRN3 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SECISBP2 | c.1888A>G p.R630G | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SEMA3B | c.1219del p.L407Sfs*52 | Frame Shift Del (DEL) | VAF 89/223 reads (40%) | called by mutect2, pindel, varscan2
- SEMG1 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 133/230 reads (58%) | SIFT tolerated (0.47); PolyPhen benign (0.006); called by muse, varscan2
- SHISAL1 | c.370A>G p.N124D | Missense Mutation (SNP) | VAF 34/349 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SHOC1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- SHPRH | c.4889A>G p.H1630R (on ENST00000275233 / NM_001042683.3; = p.H1634R on NM_173082.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- SI | c.4760A>G p.Y1587C | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIPA1L1 | c.172dup p.R58Pfs*3 | Frame Shift Ins (INS) | VAF 46/118 reads (39%) | called by mutect2, varscan2
- SLC12A6 | c.895G>T p.A299S (on ENST00000354181 / NM_001365088.1; = p.A248S on NM_005135.2) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- SLC16A2 | c.574A>G p.S192G | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SLC17A5 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A42 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 129/222 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLC25A53 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC28A3 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SLC39A1 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- SLC39A9 | c.710T>A p.L237H | Missense Mutation (SNP) | VAF 102/198 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLCO1C1 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNAPC1 | c.639del p.F213Lfs*7 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- SNAPC4 | c.3025C>A p.L1009M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SNX2 | c.1522T>C p.W508R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOGA1 | c.1469dup p.P491Sfs*2 | Frame Shift Ins (INS) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- SOX17 | c.458dup p.G154Rfs*8 | Frame Shift Ins (INS) | VAF 20/33 reads (61%) | called by mutect2, pindel, varscan2
- SPACA3 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SPAG11B | c.246dup p.S83Lfs*3 | Frame Shift Ins (INS) | VAF 70/157 reads (45%) | called by mutect2, pindel, varscan2
- SPG7 | c.1145del p.R382Lfs*50 (on ENST00000268704; = p.R389Lfs*50 on NM_003119.4) | Frame Shift Del (DEL) | VAF 45/151 reads (30%) | called by mutect2, pindel, varscan2
- SPG7 | c.1742C>T p.T581M (on ENST00000268704; = p.T588M on NM_003119.4) | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPIN1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SRSF5 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SSX5 | c.475A>G p.R159G (on ENST00000347757 / NM_175723.1; = p.R200G on NM_021015.4) | Missense Mutation (SNP) | VAF 141/362 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- STIL | c.2616-3C>T | Splice Region (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- STYXL2 | c.1590C>A p.F530L | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SUPT5H | c.2146C>T p.P716S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SVIL | c.2956G>T p.D986Y (on ENST00000355867 / NM_021738.3; = p.D560Y on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SVIL | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- SYNE1 | c.5424C>A p.D1808E (on ENST00000367255 / NM_182961.4; = p.D1815E on NM_033071.3) | Missense Mutation (SNP) | VAF 104/174 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SZT2 | c.8702del p.P2901Rfs*9 (on ENST00000634258 / NM_001365999.1; = p.P2844Rfs*9 on NM_015284.4) | Frame Shift Del (DEL) | VAF 53/174 reads (30%) | called by mutect2, pindel, varscan2
- TAF15 | c.1589del p.G530Afs*116 (on ENST00000605844 / NM_139215.3; = p.G527Afs*116 on NM_003487.4) | Frame Shift Del (DEL) | VAF 40/110 reads (36%) | called by mutect2, pindel, varscan2
- TBC1D17 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCF20 | c.5173del p.Y1725Ifs*157 | Frame Shift Del (DEL) | VAF 52/139 reads (37%) | called by mutect2, pindel, varscan2
- TCF4 | c.1796A>C p.K599T | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TCF7L2 | c.598dup p.L200Pfs*10 (on ENST00000355995 / NM_001367943.1; = p.L177Pfs*10 on NM_030756.5) | Frame Shift Ins (INS) | VAF 39/171 reads (23%) | called by mutect2, pindel, varscan2
- TECTA | c.595del p.L199* | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | called by mutect2, pindel, varscan2
- TEX10 | c.1093C>A p.L365I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- TG | c.3115C>T p.P1039S | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGFBRAP1 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TIFAB | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 128/229 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TMEM236 | c.857del p.N286Tfs*7 | Frame Shift Del (DEL) | VAF 172/543 reads (32%) | called by mutect2, pindel, varscan2
- TNFRSF6B | c.154T>A p.C52S | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- TNPO2 | c.746T>C p.I249T | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNRC6A | c.2409del p.W804Gfs*99 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, varscan2
- TOB2 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TRANK1 | c.7534T>C p.S2512P | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAV22 | c.51C>T p.C17= | Splice Region (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- TRHR | c.833del p.L278Yfs*8 | Frame Shift Del (DEL) | VAF 73/537 reads (14%) | called by mutect2, varscan2
- TRIM62 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRO | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TRPM2 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TRPV3 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSPAN16 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TSPYL2 | c.190del p.V64Wfs*83 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- TTLL8 | c.251del p.L84Cfs*40 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | called by mutect2, pindel, varscan2
- TTN | c.67667T>C p.V22556A (on ENST00000591111; = p.V15132A on NM_003319.4) | Missense Mutation (SNP) | VAF 86/257 reads (33%) | PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- TUBB2B | c.670dup p.D224Gfs*300 | Frame Shift Ins (INS) | VAF 64/229 reads (28%) | called by mutect2, pindel, varscan2
- UACA | c.3651del p.K1217Nfs*2 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | called by mutect2, pindel, varscan2
- UBC | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 86/341 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- USP3 | c.177del p.K59Nfs*10 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- VAV2 | c.2527_2529del p.V843del (on ENST00000371850 / NM_001134398.2; = p.V804del on NM_003371.4) | In Frame Del (DEL) | VAF 30/100 reads (30%) | called by pindel, varscan2
- VCAN | c.8435T>C p.L2812S | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- VN1R5 | c.311T>C p.L104S | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS13C | c.9551dup p.L3184Ffs*7 (on ENST00000644861 / NM_020821.3; = p.L3141Ffs*7 on NM_017684.5) | Frame Shift Ins (INS) | VAF 31/80 reads (39%) | called by mutect2, pindel, varscan2
- WWOX | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 33/433 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XRCC1 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- XYLT2 | c.1583_1584del p.P528Rfs*17 | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB1 | c.586del p.S196Vfs*36 | Frame Shift Del (DEL) | VAF 43/115 reads (37%) | called by mutect2, pindel, varscan2
- ZBTB14 | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZC3H13 | c.2988del p.G997Dfs*40 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- ZDHHC7 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZFAND2B | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- ZFP36L2 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZHX1 | c.1525A>T p.K509* | Nonsense Mutation (SNP) | VAF 83/307 reads (27%) | called by muse, mutect2, varscan2
- ZNF207 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF22 | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF292 | c.7633del p.R2545Gfs*14 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | called by mutect2, pindel, varscan2
- ZNF329 | c.394T>C p.S132P | Missense Mutation (SNP) | VAF 66/124 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF408 | c.393C>T p.S131= | Splice Region (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- ZNF433 | c.447del p.K149Nfs*42 | Frame Shift Del (DEL) | VAF 52/150 reads (35%) | called by mutect2, pindel, varscan2
- ZNF571 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF671 | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF785 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- ZNF800 | c.1247T>C p.V416A | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNFX1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZSCAN18 | c.929del p.P310Lfs*119 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- ZSWIM8 | c.1076A>G p.K359R | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ABL2 | c.2034G>A p.Q678= (on ENST00000502732 / NM_007314.4; = p.Q663= on NM_005158.5) | Silent (SNP) | VAF 100/298 reads (34%) | catalogued as rs1172969129, COSV100772991; called by muse, mutect2, varscan2
- ACBD5 | c.1455G>A p.L485= (on ENST00000375888 / NM_001352568.1; = p.L476= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV65520972; called by muse, mutect2, varscan2
- ACTR1A | c.756T>C p.G252= | Silent (SNP) | VAF 53/215 reads (25%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.4158C>T p.H1386= | Silent (SNP) | VAF 47/142 reads (33%) | called by muse, mutect2, varscan2
- AKR1B15 | c.210C>T p.H70= | Silent (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- ALDH3B1 | c.1092G>A p.L364= | Silent (SNP) | VAF 68/134 reads (51%) | called by muse, mutect2, varscan2
- ALOX15 | c.1977T>C p.S659= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs1567645934; called by muse, mutect2, varscan2
- ALPK3 | c.492A>G p.S164= | Silent (SNP) | VAF 46/114 reads (40%) | called by muse, mutect2, varscan2
- ANKRD27 | c.2571C>T p.F857= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs747317563, COSV60137081; called by muse, mutect2, varscan2
- ANKS1B | c.3651C>T p.R1217= (on ENST00000547776 / NM_152788.4; = p.R383= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs369534902; called by muse, mutect2, varscan2
- AP002748.5 | c.1689G>A p.A563= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs373397428; called by muse, mutect2, varscan2
- ARHGAP27 | c.1956G>A p.A652= (on ENST00000428638 / NM_001282290.1; = p.A311= on NM_199282.3) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1434570137, COSV65357419; called by muse, mutect2, varscan2
- ARHGAP4 | c.1068C>T p.D356= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs368446618, COSV63130612, COSV63131811; called by muse, mutect2, varscan2
- ARVCF | c.2739C>T p.G913= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs763994428; called by muse, mutect2, varscan2
- ASAP3 | c.759C>A p.A253= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- ATP1A4 | c.1554G>A p.P518= | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as rs142215427, COSV63625731; called by muse, mutect2, varscan2
- ATP8B4 | c.3304C>A p.R1102= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as rs749661483, COSV52713576; called by muse, mutect2, varscan2
- BRWD3 | c.2184G>A p.A728= | Silent (SNP) | VAF 67/164 reads (41%) | catalogued as rs369118921; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- C7orf25 | c.1092G>A p.T364= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as rs771011012; called by muse, mutect2, varscan2
- CATSPER4 | c.993C>T p.G331= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs201719884; called by muse, mutect2, varscan2
- CCNB3 | c.3612A>G p.Q1204= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV52079961; called by muse, mutect2, varscan2
- CD300A | c.444T>C p.F148= | Silent (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- CDHR2 | c.1431G>A p.R477= | Silent (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- CDK16 | c.885C>T p.N295= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs1470221384, COSV99331675; called by muse, mutect2, varscan2
- CENPT | c.1140C>T p.D380= | Silent (SNP) | VAF 76/162 reads (47%) | catalogued as rs374799764; called by muse, mutect2, varscan2
- CFAP65 | c.3492C>T p.P1164= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs568903495; called by muse, mutect2, varscan2
- CFAP65 | c.1011T>C p.A337= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV55391737; called by muse, mutect2, varscan2
- CNOT10 | c.1527T>C p.H509= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.3132G>A p.P1044= | Silent (SNP) | VAF 55/128 reads (43%) | catalogued as rs761663690, COSV62146496, COSV62147352; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CNTNAP4 | c.2190C>T p.C730= | Silent (SNP) | VAF 55/153 reads (36%) | called by muse, mutect2, varscan2
- COL4A6 | c.2601C>T p.G867= | Silent (SNP) | VAF 94/271 reads (35%) | catalogued as COSV57863990; called by muse, mutect2, varscan2
- COX6A1 | c.297G>A p.V99= | Silent (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- CYLC1 | c.1773A>G p.K591= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV61410774; called by muse, mutect2, varscan2
- DCAF4L2 | c.429G>A p.L143= | Silent (SNP) | VAF 117/174 reads (67%) | catalogued as rs1287205017, COSV60478747; called by muse, mutect2, varscan2
- DHRS12 | c.294G>T p.V98= (on ENST00000444610 / NM_001377930.1; = p.V49= on NM_024705.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2
- DHX34 | c.270C>A p.I90= | Silent (SNP) | VAF 62/183 reads (34%) | called by muse, mutect2, varscan2
- DLG5 | c.5754G>A p.P1918= | Silent (SNP) | VAF 79/253 reads (31%) | catalogued as rs148200124; called by muse, mutect2, varscan2
- DMRTC2 | c.231C>T p.R77= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- DNAJB8 | c.636C>T p.D212= | Silent (SNP) | VAF 103/220 reads (47%) | catalogued as rs374525334; called by muse, mutect2, varscan2
- DOCK4 | c.3444C>T p.G1148= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1178482244, COSV69854832; called by muse, mutect2, varscan2
- DRD5 | c.993C>T p.A331= | Silent (SNP) | VAF 93/183 reads (51%) | catalogued as rs1560112874; called by muse, mutect2, varscan2
- DSCC1 | c.975G>A p.L325= | Silent (SNP) | VAF 50/214 reads (23%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.11659C>T p.L3887= | Silent (SNP) | VAF 63/139 reads (45%) | called by muse, mutect2, varscan2
- DYRK1B | c.1572G>A p.K524= | Silent (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- E4F1 | c.690C>T p.R230= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1161743687; called by muse, mutect2, varscan2
- EDIL3 | c.1419G>T p.L473= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs1021343265; called by muse, mutect2, varscan2
- ESX1 | c.1110G>A p.P370= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV65424227, COSV65424250; called by muse, varscan2
- EVA1B | c.345G>T p.S115= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV54634028; called by muse, mutect2, varscan2
- FAM160A2 | c.1914G>A p.V638= (on ENST00000449352 / NM_001098794.2; = p.V652= on NM_032127.4) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1448946512; called by muse, mutect2, varscan2
149 further variants in this file (0 protein-altering or splice-affecting, 135 silent, 14 other) are not listed here.
